FM case AD7202 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/e9dd14e3-8929-44ab-8bfd-dc36fa16eda0

Female, 75.3 years: diagnosis not reported by GDC; metastasis biopsied or resected from the cervix uteri. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
